Somatic mutation profile of tumor specimen MMRF_2172_1_BM_CD138pos (aliquot MMRF_2172_1_BM_CD138pos_T1_KHS5U_L08697) from MMRF case MMRF_2172, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.4 years (26,456 days).
Specimen MMRF_2172_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a9c5797-9e87-4bd1-94d8-5f12f1190723.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2172_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2172_1_PB_CD3pos_C3_KHS5U_L08696; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de636833-06da-41ca-b303-630003ea35f0

The open-access MAF lists 111 somatic variants for this specimen: 43 protein-altering or splice-affecting, 11 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 32, Intron 14, Silent 11, 5'UTR 6, Nonsense Mutation 4, 3'Flank 3, Splice Site 2, In Frame Ins 1, Splice Region 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.487T>G p.Y163D | Missense Mutation (SNP) | VAF 14/208 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: likely pathogenic; called by muse, mutect2
- ADAMTS10 | c.1568C>T p.T523M | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs782308360, COSV54358492; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKS1B | c.1105G>A p.G369R | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV101612660; called by muse, mutect2
- EIF3B | c.1513C>T p.R505* | Nonsense Mutation (SNP) | VAF 15/231 reads (6%) | catalogued as COSV62803923; called by muse, mutect2
- EPPK1 | c.5017G>A p.V1673I | Missense Mutation (SNP) | VAF 39/333 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as rs564091699, COSV101599844; called by muse, mutect2, varscan2
- GRIN3B | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs751030090; called by muse, mutect2, varscan2
- IGHV2-70 | c.161G>C p.C54S | Missense Mutation (SNP) | VAF 144/265 reads (54%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs368641348; called by muse, varscan2
- IGHV2-70 | c.134G>C p.G45A | Missense Mutation (SNP) | VAF 74/184 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs376985995; called by muse, varscan2
- IGLV3-19 | c.203G>C p.G68A | Missense Mutation (SNP) | VAF 83/83 reads (100%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as rs376663286; called by muse, mutect2, varscan2
- IGLV4-69 | c.230G>C p.S77T | Missense Mutation (SNP) | VAF 157/308 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs113792022; called by muse, mutect2, varscan2
- LRCOL1 | c.89T>C p.L30S | Missense Mutation (SNP) | VAF 70/158 reads (44%) | PolyPhen benign (0.017); catalogued as rs892290923; called by muse, mutect2, varscan2
- MAGEB17 | c.290G>A p.G97D | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs1402613543; called by muse, mutect2, varscan2
- MTA2 | c.1604C>G p.P535R | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.218); catalogued as rs1470009643; called by muse, mutect2
- PDGFC | c.205A>G p.R69G | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1320903452, COSV56847936; called by muse, mutect2, varscan2
- PRDM9 | c.315G>A p.W105* | Nonsense Mutation (SNP) | VAF 32/496 reads (6%) | catalogued as rs759768731, COSV57002662; called by muse, mutect2
- RCSD1 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 83/273 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.085); catalogued as COSV63258825; called by muse, mutect2, varscan2
- SEMA6C | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs1423768913, COSV59003796; called by muse, mutect2
- TMEM132B | c.2500C>T p.R834C | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV54760830; called by muse, mutect2, varscan2
- TRIM66 | c.118A>G p.M40V | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs779079290; called by muse, mutect2, varscan2
- TSHZ2 | c.2863G>A p.D955N | Missense Mutation (SNP) | VAF 153/321 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1358648334, COSV61586874; called by muse, mutect2, varscan2
- ZC3H7B | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs1406262133, COSV100687411; called by muse, mutect2
- ADAM32 | c.762A>T p.L254F | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- C4orf51 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 187/397 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CCSER2 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 39/375 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- CD200 | c.168A>T p.Q56H (on ENST00000473539 / NM_001004196.3; = p.Q31H on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- COL12A1 | c.4418-8T>C | Splice Region (SNP) | VAF 10/199 reads (5%) | called by muse, mutect2
- COL6A3 | c.9366G>C p.R3122S | Missense Mutation (SNP) | VAF 159/410 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- COL9A1 | c.167-2A>G p.X56_splice | Splice Site (SNP) | VAF 142/155 reads (92%) | called by muse, varscan2
- CREBBP | c.1330+2T>A p.X444_splice | Splice Site (SNP) | VAF 199/407 reads (49%) | called by muse, mutect2, varscan2
- DGKE | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 21/215 reads (10%) | called by muse, mutect2
- DNASE1L2 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 70/132 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP2 | c.11114G>A p.C3705Y | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NADK | c.1326_1327insAAG p.E442_E443insK | In Frame Ins (INS) | VAF 184/342 reads (54%) | called by pindel, varscan2
- NUF2 | c.1068A>C p.Q356H | Missense Mutation (SNP) | VAF 14/452 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- OTOG | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 115/265 reads (43%) | called by muse, mutect2, varscan2
- PRUNE2 | c.1621G>A p.G541S | Missense Mutation (SNP) | VAF 96/192 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- RCC1 | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RYR3 | c.5029G>A p.E1677K | Missense Mutation (SNP) | VAF 158/314 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.175); called by muse, varscan2
- SLC6A1 | c.755T>C p.I252T | Missense Mutation (SNP) | VAF 18/427 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.049); called by muse, mutect2
- SNX25 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- TAF9 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 84/154 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ZFYVE9 | c.1500T>A p.D500E | Missense Mutation (SNP) | VAF 98/233 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF45 | c.430G>C p.G144R | Missense Mutation (SNP) | VAF 18/384 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2
- ATP5MC2 | c.411C>T p.I137= | Silent (SNP) | VAF 79/163 reads (48%) | called by muse, mutect2, varscan2
- C7 | c.2412T>C p.I804= | Silent (SNP) | VAF 168/348 reads (48%) | called by muse, mutect2, varscan2
- CDKN1C | c.99C>G p.L33= | Silent (SNP) | VAF 77/154 reads (50%) | catalogued as rs960994716; called by muse, mutect2, varscan2
- DMRTA1 | c.465G>A p.G155= | Silent (SNP) | VAF 53/123 reads (43%) | catalogued as rs779087748; called by muse, mutect2, varscan2
- DRP2 | c.309C>T p.H103= | Silent (SNP) | VAF 86/89 reads (97%) | called by muse, mutect2, varscan2
- IGLV2-23 | c.288C>T p.I96= | Silent (SNP) | VAF 61/128 reads (48%) | catalogued as rs376155748; called by muse, varscan2
- JAKMIP1 | c.315C>T p.I105= | Silent (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- KIF4B | c.1194G>A p.E398= | Silent (SNP) | VAF 88/203 reads (43%) | catalogued as COSV101469204; called by muse, mutect2, varscan2
- PFKP | c.1185G>A p.K395= | Silent (SNP) | VAF 10/282 reads (4%) | called by muse, mutect2
- XPOT | c.1854G>A p.R618= | Silent (SNP) | VAF 42/95 reads (44%) | called by muse, mutect2, varscan2
- ZIC3 | c.624C>T p.D208= | Silent (SNP) | VAF 6/146 reads (4%) | called by muse, mutect2
- ANTXR2 | c.*5102A>G | 3'UTR (SNP) | VAF 47/109 reads (43%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.*3843G>A | 3'UTR (SNP) | VAF 75/83 reads (90%) | called by muse, mutect2, varscan2
- ASIC1 | c.1297+18C>T | Intron (SNP) | VAF 101/197 reads (51%) | called by muse, mutect2, varscan2
- B3GAT2 | c.*2923G>T | 3'UTR (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- C3orf80 | c.-74G>C | 5'UTR (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- CACNA1E | c.*8557G>A | 3'UTR (SNP) | VAF 151/542 reads (28%) | called by muse, mutect2, varscan2
- CASK | chrX:41518050 T>C | 3'Flank (SNP) | VAF 52/52 reads (100%) | catalogued as rs1465861262; called by muse, mutect2, varscan2
- CBX2 | c.288+460G>C | Intron (SNP) | VAF 42/93 reads (45%) | called by muse, mutect2, varscan2
- CDSN | c.*164C>A | 3'UTR (SNP) | VAF 72/156 reads (46%) | called by muse, mutect2, varscan2
- COMT | c.615+599C>T | Intron (SNP) | VAF 99/199 reads (50%) | called by muse, mutect2, varscan2
- CREB1 | c.881+195A>G | Intron (SNP) | VAF 36/104 reads (35%) | catalogued as rs776972778; called by muse, mutect2, varscan2
- CUL4B | c.68-90A>G | Intron (SNP) | VAF 52/55 reads (95%) | catalogued as rs935558933; called by muse, mutect2, varscan2
- DCDC2 | c.*1125A>G | 3'UTR (SNP) | VAF 90/206 reads (44%) | catalogued as rs1216941878; called by muse, varscan2
- EIF4E2 | c.135+45T>C | Intron (SNP) | VAF 24/372 reads (6%) | catalogued as rs201272768; called by mutect2, varscan2
- FBXL4 | chr6:98873565 A>G | 3'Flank (SNP) | VAF 48/57 reads (84%) | called by muse, mutect2, varscan2
- FGFR3 | c.*191T>A | 3'UTR (SNP) | VAF 10/218 reads (5%) | called by muse, mutect2
- FGFR3 | chr4:1808435 A>G | 3'Flank (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- GNPDA2 | c.769+258A>C | Intron (SNP) | VAF 50/114 reads (44%) | called by muse, mutect2, varscan2
- HCFC1 | c.*1741G>A | 3'UTR (SNP) | VAF 6/61 reads (10%) | catalogued as rs782579113; called by muse, mutect2
- HSD17B12 | c.*1170dup | 3'UTR (INS) | VAF 41/84 reads (49%) | catalogued as rs973896924; called by mutect2, varscan2
- ICMT | c.*785G>A | 3'UTR (SNP) | VAF 103/211 reads (49%) | catalogued as rs775175523; called by muse, mutect2, varscan2
- KCNT2 | c.*1507G>A | 3'UTR (SNP) | VAF 72/265 reads (27%) | called by muse, mutect2, varscan2
- KDSR | c.*3496T>G | 3'UTR (SNP) | VAF 46/148 reads (31%) | called by muse, mutect2, varscan2
- KLF3 | c.*483T>C | 3'UTR (SNP) | VAF 118/257 reads (46%) | called by muse, mutect2, varscan2
- KLHL6 | c.*2128T>G | 3'UTR (SNP) | VAF 9/154 reads (6%) | called by muse, mutect2
- LARP4 | c.*1925A>C | 3'UTR (SNP) | VAF 72/159 reads (45%) | called by muse, mutect2, varscan2
- LEPROTL1 | c.279+475G>A | Intron (SNP) | VAF 6/17 reads (35%) | catalogued as rs1353066812; called by muse, mutect2, varscan2
- MATK | chr19:3789347 T>C | 5'Flank (SNP) | VAF 81/165 reads (49%) | called by muse, mutect2, varscan2
- MROH7 | c.2964+2192C>T | Intron (SNP) | VAF 88/789 reads (11%) | catalogued as COSV59873524; called by muse, mutect2, varscan2
- NBEAL1 | c.*101C>T | 3'UTR (SNP) | VAF 37/75 reads (49%) | called by muse, mutect2, varscan2
- NHLH2 | c.-8-182A>G | Intron (SNP) | VAF 69/77 reads (90%) | called by muse, mutect2, varscan2
- NIPAL3 | c.*2775A>G | 3'UTR (SNP) | VAF 22/46 reads (48%) | called by muse, varscan2
- NIPAL3 | c.*3122A>G | 3'UTR (SNP) | VAF 59/120 reads (49%) | called by muse, mutect2, varscan2
- NKX3-1 | c.*1191C>A | 3'UTR (SNP) | VAF 8/145 reads (6%) | called by muse, mutect2
- NLRP7 | c.2810+2771C>A | Intron (SNP) | VAF 75/181 reads (41%) | catalogued as COSV60179279; called by muse, mutect2
- NOS1 | c.*682G>A | 3'UTR (SNP) | VAF 70/147 reads (48%) | called by muse, mutect2, varscan2
- PCDH19 | c.-458G>A | 5'UTR (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- PDGFC | c.-523C>T | 5'UTR (SNP) | VAF 22/38 reads (58%) | called by muse, mutect2, varscan2
- PDLIM5 | c.*3298T>C | 3'UTR (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- PHLPP1 | c.*79G>C | 3'UTR (SNP) | VAF 20/795 reads (3%) | called by muse, mutect2
- PNMA2 | c.-323G>A | 5'UTR (SNP) | VAF 134/252 reads (53%) | catalogued as rs534947511, COSV101580650; called by muse, mutect2, varscan2
- RAB22A | c.*2291C>T | 3'UTR (SNP) | VAF 63/127 reads (50%) | called by muse, mutect2, varscan2
- RARA | c.328-36G>C | Intron (SNP) | VAF 29/69 reads (42%) | called by muse, mutect2, varscan2
- ROBO2 | c.-860C>T | 5'UTR (SNP) | VAF 6/15 reads (40%) | called by mutect2, varscan2
- SEZ6 | c.*571A>G | 3'UTR (SNP) | VAF 135/276 reads (49%) | called by muse, mutect2, varscan2
- SSBP1 | c.24+222T>C | Intron (SNP) | VAF 16/25 reads (64%) | called by muse, mutect2
- STAG3L4 | n.1828T>G | RNA (SNP) | VAF 245/511 reads (48%) | called by muse, mutect2, varscan2
- STRN | c.*3415T>A | 3'UTR (SNP) | VAF 6/80 reads (8%) | catalogued as rs1051480181, COSV55753357; called by muse, mutect2
- TP63 | c.*819T>A | 3'UTR (SNP) | VAF 98/198 reads (49%) | called by muse, mutect2, varscan2
- TP63 | c.*2484del | 3'UTR (DEL) | VAF 44/118 reads (37%) | catalogued as rs1484082829; called by mutect2, varscan2
- TRAF3 | c.*763A>T | 3'UTR (SNP) | VAF 8/115 reads (7%) | called by muse, mutect2
- U2SURP | c.*440C>T | 3'UTR (SNP) | VAF 85/226 reads (38%) | called by muse, mutect2, varscan2
- UNC5D | c.*4082G>T | 3'UTR (SNP) | VAF 49/121 reads (40%) | called by muse, mutect2, varscan2
- VPS13A | c.6379-873G>A | Intron (SNP) | VAF 10/277 reads (4%) | called by muse, mutect2
- VPS52 | c.-106A>C | 5'UTR (SNP) | VAF 18/244 reads (7%) | called by muse, mutect2
- ZNF460 | c.*48T>A | 3'UTR (SNP) | VAF 14/244 reads (6%) | called by muse, mutect2
- ZNHIT6 | c.*253T>C | 3'UTR (SNP) | VAF 146/154 reads (95%) | called by muse, varscan2
